Somatic mutation profile of tumor specimen C3N-02030-03 (aliquot CPT0133780087) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 464af750-a6ad-4b05-bc32-533abc54499a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86d1a1dc-bcb4-49ca-85d2-34312c32fb9c

The open-access MAF lists 749 somatic variants for this specimen: 505 protein-altering or splice-affecting, 159 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 350, Silent 159, Frame Shift Del 87, Intron 53, Frame Shift Ins 25, Nonsense Mutation 24, 3'UTR 10, Splice Site 9, 5'UTR 6, 3'Flank 6, RNA 6, In Frame Del 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 122/353 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 58/107 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 140/378 reads (37%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 64/420 reads (15%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 59/220 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 261/472 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 108/304 reads (36%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 78/217 reads (36%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 28/166 reads (17%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- ADCK5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 15/463 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370821655; called by muse, mutect2
- ADGRL3 | c.2165G>A p.W722* (on ENST00000506720 / NM_001322402.2; = p.W654* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 18/286 reads (6%) | catalogued as COSV72231841; called by muse, mutect2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 163/251 reads (65%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 38/270 reads (14%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 138/355 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ANK3 | c.3361C>T p.R1121C (on ENST00000280772 / NM_001320874.2; = p.R255C on NM_001149.3) | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759013111, COSV55064344; called by muse, mutect2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 192/525 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 134/326 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- ATRNL1 | c.576del p.F192Lfs*8 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as rs1554873914; called by mutect2, pindel
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 46/207 reads (22%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- BCL11A | c.2087C>T p.P696L (on ENST00000335712 / NM_001365609.1; = p.P730L on NM_018014.4) | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs1432244779; called by muse, mutect2, varscan2
- BCL11A | c.1135G>A p.A379T (on ENST00000335712 / NM_001365609.1; = p.A413T on NM_018014.4) | Missense Mutation (SNP) | VAF 13/436 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59634142; called by muse, mutect2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 61/324 reads (19%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 34/156 reads (22%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 44/492 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 273/680 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 11/75 reads (15%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP206 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1333669635; called by muse, mutect2, varscan2
- CFAP46 | c.4868C>T p.S1623L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1018417455; called by muse, mutect2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- CNST | c.1096A>G p.S366G | Missense Mutation (SNP) | VAF 32/546 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.47); catalogued as rs753946956; called by muse, mutect2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 55/103 reads (53%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2, varscan2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 216/510 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- COQ8A | c.972G>A p.W324* | Nonsense Mutation (SNP) | VAF 47/860 reads (5%) | catalogued as rs1350444582, COSV64656717; called by muse, mutect2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, varscan2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2, varscan2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 109/296 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 111/233 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 191/420 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 171/382 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 169/583 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DMXL1 | c.7033C>T p.R2345W | Missense Mutation (SNP) | VAF 22/445 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147021587; called by muse, mutect2
- DNHD1 | c.13360C>T p.Q4454* | Nonsense Mutation (SNP) | VAF 14/316 reads (4%) | catalogued as COSV99599303; called by muse, mutect2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 40/139 reads (29%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- DTX1 | c.1111G>A p.V371M | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs890968014; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- ELOA2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 44/1151 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs974032541, COSV55308374, COSV55309189; called by muse, mutect2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2, varscan2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- ERG | c.368del p.P123Qfs*3 | Frame Shift Del (DEL) | VAF 13/106 reads (12%) | catalogued as COSV99902869; called by mutect2, pindel, varscan2
- FAAP100 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as rs1392568088; called by muse, mutect2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 157/429 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM47A | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV60496771; called by muse, mutect2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, mutect2, varscan2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 290/723 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 127/881 reads (14%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FOXE1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64300120; called by muse, mutect2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 52/327 reads (16%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- GJD4 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.27); catalogued as COSV58701999; called by muse, mutect2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 36/100 reads (36%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, mutect2, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 41/476 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2
- HLF | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1040249035, COSV56831325; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 88/320 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITCH | c.1154C>T p.T385M (on ENST00000262650 / NM_001257137.3; = p.T344M on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1324908711, COSV52935548; called by muse, mutect2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 102/255 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- KCNA3 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1234028653; called by muse, mutect2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 87/226 reads (38%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM5A | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV66990391; called by muse, mutect2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 132/327 reads (40%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KIAA1109 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs563356557; called by muse, mutect2
- KIDINS220 | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 31/353 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs773095081, COSV56755745; called by muse, mutect2
- KIF26A | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs1462761829; called by muse, mutect2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2, varscan2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LAMP1 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs909984779; called by muse, mutect2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LOX | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 24/345 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.07); catalogued as rs1463695782; called by muse, mutect2
- LRRC71 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 23/483 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs913176720; called by muse, mutect2
- LTBP1 | c.2704G>A p.E902K (on ENST00000404816 / NM_206943.4; = p.E576K on NM_000627.4) | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs755917287, COSV63197620; called by muse, mutect2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 41/134 reads (31%) | catalogued as rs1321319432; called by mutect2, pindel, varscan2
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 122/284 reads (43%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 227/522 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NCOA5 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774397965, COSV51643562; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 31/189 reads (16%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 47/140 reads (34%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 214/507 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- NUP188 | c.287A>G p.Y96C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101001175; called by muse, mutect2
- OBSL1 | c.5045G>A p.R1682H | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs1479080818; called by muse, mutect2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 34/111 reads (31%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 51/480 reads (11%) | catalogued as COSV63382218; called by mutect2, pindel, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 134/329 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR12D2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs752585138, COSV65828725; called by mutect2, varscan2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 164/394 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 93/223 reads (42%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- OTUD7B | c.1976del p.G659Vfs*169 | Frame Shift Del (DEL) | VAF 34/247 reads (14%) | catalogued as COSV100967422; called by mutect2, pindel, varscan2
- PARD3B | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV62502529; called by muse, mutect2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 62/158 reads (39%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 28/73 reads (38%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCARE | c.2966del p.P989Lfs*46 | Frame Shift Del (DEL) | VAF 24/250 reads (10%) | catalogued as rs770881706; called by mutect2, pindel
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 136/372 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs1262793592; called by mutect2, pindel, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | catalogued as rs759495724; called by mutect2, varscan2
- PDZD2 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 35/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56854841; called by muse, mutect2, varscan2
- PFAS | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752626863; called by muse, mutect2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 110/382 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.5219A>G p.K1740R | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1390556648, COSV55402756; called by muse, mutect2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 18/126 reads (14%) | catalogued as rs755089774; called by pindel, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 112/361 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLK | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); catalogued as COSV99605417; called by muse, mutect2, varscan2
- POLR3GL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370170498; called by muse, mutect2
- PPP4R2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1230961376; called by muse, mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 271/620 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PRDM9 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 29/440 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV57006227; called by muse, mutect2
- PRELP | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs769050745; called by muse, mutect2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 209/543 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | catalogued as rs1234606471; called by mutect2, varscan2
- PXDN | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs753691649; called by muse, mutect2, varscan2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2, varscan2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SART3 | c.2063G>A p.C688Y (on ENST00000228284; = p.C670Y on NM_014706.4) | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs755365964, COSV57206827; called by muse, mutect2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as rs763290832; called by mutect2, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | catalogued as rs771002611; called by mutect2, pindel, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs1270083658; called by mutect2, pindel, varscan2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 126/296 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 38/92 reads (41%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SKIV2L | c.1637del p.G546Afs*83 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV64814087; called by mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 112/360 reads (31%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 129/305 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SLC4A5 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 23/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753286986; called by muse, mutect2
- SLITRK1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV65675639; called by muse, mutect2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs763364024; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 76/320 reads (24%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 59/162 reads (36%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 212/450 reads (47%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, mutect2, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 75/677 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- TAF1 | c.1877del p.K626Rfs*4 (on ENST00000373790 / NM_138923.4; = p.K647Rfs*4 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | catalogued as rs745516519; called by mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 41/84 reads (49%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 61/146 reads (42%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRD1 | c.2825T>C p.I942T | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1167808824; called by muse, mutect2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 77/452 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TENT5B | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56693344; called by muse, mutect2, varscan2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 145/359 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TM9SF2 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs767936414; called by muse, mutect2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 31/217 reads (14%) | catalogued as rs770800449; called by mutect2, varscan2
- TOGARAM2 | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1323135738; called by mutect2, varscan2
- TRAPPC12 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV60845878; called by muse, mutect2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 163/398 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TTLL1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1569403339, COSV56740189; called by muse, mutect2
- TTLL12 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV53354093; called by muse, mutect2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- UBR4 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV100920686; called by muse, mutect2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- USP4 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs746404183; called by muse, mutect2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2
- WDR4 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374998; called by muse, mutect2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 141/427 reads (33%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 88/204 reads (43%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 87/284 reads (31%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 239/572 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 170/477 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 26/190 reads (14%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 82/181 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 26/92 reads (28%) | called by mutect2, pindel, varscan2
- ALG13 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- AMER2 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.057); called by muse, mutect2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- AOX1 | c.1547G>T p.R516M | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- AP4B1 | c.618-7dup | Splice Region (INS) | VAF 17/132 reads (13%) | called by mutect2, pindel, varscan2
- APBA2 | c.1918-1G>T p.X640_splice | Splice Site (SNP) | VAF 59/466 reads (13%) | called by muse, mutect2, varscan2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 26/206 reads (13%) | called by mutect2, pindel, varscan2
- ARID1A | c.3344del p.P1115Qfs*46 | Frame Shift Del (DEL) | VAF 32/337 reads (9%) | called by mutect2, pindel
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 70/178 reads (39%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BCKDK | c.1042del p.L348Sfs*156 | Frame Shift Del (DEL) | VAF 26/274 reads (9%) | called by mutect2, pindel
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 89/449 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C1orf68 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 37/658 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); called by muse, mutect2
- CARMIL3 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 38/101 reads (38%) | called by mutect2, pindel, varscan2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 152/317 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 86/189 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELF3 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 93/223 reads (42%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CLMN | c.1484del p.L495Wfs*18 | Frame Shift Del (DEL) | VAF 19/184 reads (10%) | called by mutect2, pindel, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 68/170 reads (40%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 145/344 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 100/274 reads (36%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 54/170 reads (32%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 115/311 reads (37%) | called by muse, mutect2, varscan2
- CYB561D2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DAAM1 | c.2663+4_2663+7del p.X888_splice | Splice Site (DEL) | VAF 16/82 reads (20%) | called by pindel, varscan2
- DCAF4 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- DCAF8L2 | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 17/309 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- DCBLD1 | c.114T>C p.G38= | Splice Region (SNP) | VAF 15/208 reads (7%) | called by muse, mutect2
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 142/405 reads (35%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 154/747 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DENND1A | c.1940C>A p.A647D | Missense Mutation (SNP) | VAF 26/399 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DHTKD1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 16/534 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 155/394 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 93/201 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 36/148 reads (24%) | called by muse, mutect2, varscan2
- DPH2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- DSG3 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- DVL1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 89/261 reads (34%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 93/262 reads (35%) | called by mutect2, pindel, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EIF4A1 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/115 reads (19%) | called by mutect2, pindel, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ERAP1 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 43/583 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- ERF | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 10/301 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 46/131 reads (35%) | called by mutect2, pindel, varscan2
- EXOC4 | c.33A>C p.R11S | Missense Mutation (SNP) | VAF 25/273 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.264); called by muse, mutect2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 235/527 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 58/225 reads (26%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 123/322 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FLT4 | c.2251T>C p.C751R | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 88/301 reads (29%) | called by mutect2, pindel, varscan2
- FNBP4 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 69/198 reads (35%) | called by mutect2, pindel, varscan2
- FOXP4 | c.1696A>G p.S566G (on ENST00000307972 / NM_001012426.1; = p.S553G on NM_138457.3) | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 146/309 reads (47%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 107/435 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALK1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GAREM1 | c.1916G>A p.R639K (on ENST00000269209 / NM_001242409.2; = p.R638K on NM_022751.3) | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGTLC1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 72/828 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 135/354 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GNE | c.1540G>T p.G514* (on ENST00000396594 / NM_001128227.3; = p.G483* on NM_005476.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/471 reads (4%) | called by muse, mutect2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 207/873 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPATCH1 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 74/213 reads (35%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 26/186 reads (14%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2BC12 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2
- HDAC11 | c.369+2T>C p.X123_splice | Splice Site (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- HDAC5 | c.2463+2T>C p.X821_splice | Splice Site (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 66/215 reads (31%) | called by pindel, varscan2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 106/253 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 203/490 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 130/298 reads (44%) | called by mutect2, pindel, varscan2
- IL6ST | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 35/109 reads (32%) | called by mutect2, pindel, varscan2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 135/294 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 20/143 reads (14%) | called by mutect2, pindel, varscan2
- ITGA1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 188/420 reads (45%) | called by mutect2, varscan2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 72/158 reads (46%) | called by mutect2, pindel
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 127/361 reads (35%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 146/365 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KCNH1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); called by muse, mutect2
- KCNJ10 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 32/750 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- KDM4B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KEL | c.1969C>A p.H657N | Missense Mutation (SNP) | VAF 50/459 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF1A | c.4946C>T p.T1649I (on ENST00000320389 / NM_001379639.1; = p.T1641I on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.894); called by muse, mutect2
- KIF1A | c.1637A>T p.D546V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 168/985 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 46/127 reads (36%) | called by muse, mutect2, varscan2
- KMT2D | c.14818C>T p.P4940S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMA2 | c.7105A>G p.R2369G | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 87/252 reads (35%) | called by mutect2, pindel, varscan2
- LBR | c.1806C>A p.Y602* | Nonsense Mutation (SNP) | VAF 24/440 reads (5%) | called by muse, mutect2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.496+1G>A p.X166_splice | Splice Site (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 88/375 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 32/88 reads (36%) | called by mutect2, pindel, varscan2
- LRGUK | c.167_168del p.I56Sfs*22 | Frame Shift Del (DEL) | VAF 41/404 reads (10%) | called by mutect2, pindel, varscan2
- LRRC25 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- LRRC8C | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.019); called by muse, mutect2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 85/376 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 92/417 reads (22%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- MCM5 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 228/494 reads (46%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MFN2 | c.2070-7T>C | Splice Region (SNP) | VAF 48/531 reads (9%) | called by muse, mutect2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 168/385 reads (44%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MLH3 | c.4013T>C p.L1338P (on ENST00000355774 / NM_001040108.2; = p.L1314P on NM_014381.3) | Missense Mutation (SNP) | VAF 35/608 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MYF6 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYOF | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2
- NAA80 | c.439del p.L147* (on ENST00000417393 / NM_001200018.2; = p.L169* on NM_012191.4) | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 40/210 reads (19%) | called by mutect2, pindel, varscan2
- NKAIN3 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.965); called by muse, mutect2
- NODAL | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by muse, mutect2
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 51/359 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR4A3 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 108/306 reads (35%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | called by mutect2, pindel, varscan2
- OR7E24 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ORC5 | c.1029dup p.H344Tfs*25 | Frame Shift Ins (INS) | VAF 24/76 reads (32%) | called by mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 118/341 reads (35%) | called by mutect2, pindel, varscan2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 114/263 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 71/148 reads (48%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 158/382 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 246/570 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 70/385 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDCD1 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2
- PDE3A | c.2091del p.F697Lfs*3 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 98/425 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PIGB | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 71/164 reads (43%) | called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 110/332 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 159/392 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PNMA8B | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 177/403 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP1R16A | c.1498A>G p.R500G | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRICKLE2 | c.1027C>T p.H343Y (on ENST00000295902; = p.H287Y on NM_198859.4) | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 48/262 reads (18%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- PRRT1 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- PSMD8 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 69/195 reads (35%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 164/392 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 122/316 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- RAI14 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBL1 | c.824T>G p.I275S | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | called by mutect2, pindel
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBDF1 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RHOA | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.079); called by muse, mutect2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 20/68 reads (29%) | called by mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RPS6KA6 | c.990dup p.A331Cfs*4 | Frame Shift Ins (INS) | VAF 17/115 reads (15%) | called by mutect2, pindel, varscan2
- RUBCNL | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2
- SAGE1 | c.833dup p.N278Kfs*25 | Frame Shift Ins (INS) | VAF 18/186 reads (10%) | called by mutect2, pindel
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 239/599 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 47/297 reads (16%) | called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 55/68 reads (81%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 19/96 reads (20%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 328/793 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | called by mutect2, varscan2
- SLC25A44 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.17); called by muse, mutect2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCA4 | c.3697A>G p.M1233V | Missense Mutation (SNP) | VAF 48/634 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- SMARCAD1 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 138/458 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 65/375 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SST | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STOX1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- STUB1 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 56/495 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SUSD2 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 106/290 reads (37%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 161/495 reads (33%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 62/197 reads (31%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 250/624 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCF19 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TERB1 | c.365_368del p.S122Ffs*18 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 60/168 reads (36%) | called by mutect2, pindel, varscan2
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 122/320 reads (38%) | called by mutect2, pindel, varscan2
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 61/340 reads (18%) | called by mutect2, pindel, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 37/100 reads (37%) | called by pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 73/221 reads (33%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 59/169 reads (35%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBE3B | c.183del p.F61Lfs*44 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | called by mutect2, pindel, varscan2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VILL | c.1360A>G p.S454G | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13B | c.4130G>T p.S1377I | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- WIPI2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 34/106 reads (32%) | called by mutect2, varscan2
- ZBTB11 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 60/187 reads (32%) | called by mutect2, pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.2699T>C p.M900T | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- ZNF236 | c.3056-2A>G p.X1019_splice | Splice Site (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 46/139 reads (33%) | called by mutect2, pindel, varscan2
- ZNF530 | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF541 | c.4030del p.L1344Cfs*56 | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | called by mutect2, pindel, varscan2
- ZNF689 | c.1134T>G p.C378W | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 124/329 reads (38%) | called by muse, mutect2, varscan2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- ANTKMT | c.687C>G p.G229= | Silent (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ARHGAP4 | c.2106T>C p.P702= | Silent (SNP) | VAF 21/500 reads (4%) | called by muse, mutect2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 95/211 reads (45%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.114G>A p.A38= | Silent (SNP) | VAF 28/190 reads (15%) | catalogued as rs1253717800; called by muse, mutect2
- B3GNT8 | c.679C>T p.L227= | Silent (SNP) | VAF 15/238 reads (6%) | called by muse, mutect2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 65/253 reads (26%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- BTBD11 | c.1509G>A p.P503= (on ENST00000280758 / NM_001018072.2; = p.P40= on NM_001017523.2) | Silent (SNP) | VAF 41/429 reads (10%) | catalogued as rs1158212649; called by muse, mutect2
- BTRC | c.1569C>T p.A523= (on ENST00000370187 / NM_033637.4; = p.A487= on NM_003939.5) | Silent (SNP) | VAF 15/175 reads (9%) | catalogued as rs11191040; called by muse, mutect2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 39/234 reads (17%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 152/406 reads (37%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CA8 | c.480G>A p.P160= | Silent (SNP) | VAF 38/530 reads (7%) | catalogued as rs537454715; called by muse, mutect2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 118/257 reads (46%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 106/221 reads (48%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 55/250 reads (22%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 26/122 reads (21%) | called by muse, mutect2, varscan2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 239/575 reads (42%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 79/151 reads (52%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- COL16A1 | c.2868C>T p.C956= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as rs183843629; called by muse, mutect2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 107/261 reads (41%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 145/377 reads (38%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- COX7B | c.69G>A p.R23= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- CTAG2 | c.570A>G p.G190= | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as rs1557241363; called by muse, mutect2
- CUBN | c.8742G>A p.A2914= | Silent (SNP) | VAF 34/726 reads (5%) | catalogued as rs142563433; called by muse, mutect2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 85/191 reads (45%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as rs771383564; called by muse, mutect2, varscan2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 72/180 reads (40%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 78/526 reads (15%) | called by muse, mutect2, varscan2
- EPB41L4B | c.1381C>A p.R461= | Silent (SNP) | VAF 17/232 reads (7%) | called by muse, mutect2
- EPN1 | c.711G>A p.R237= (on ENST00000270460 / NM_001321263.1; = p.R212= on NM_013333.3) | Silent (SNP) | VAF 19/406 reads (5%) | catalogued as COSV50039002; called by muse, mutect2
- FBXW5 | c.1617C>A p.R539= | Silent (SNP) | VAF 34/595 reads (6%) | called by muse, mutect2
- FKBP9 | c.1153C>T p.L385= | Silent (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- FLNC | c.2457C>T p.F819= | Silent (SNP) | VAF 71/703 reads (10%) | catalogued as rs761900404, COSV57951315; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXO4 | c.1173C>A p.S391= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 43/115 reads (37%) | called by muse, mutect2, varscan2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 51/284 reads (18%) | called by muse, mutect2, varscan2
- GLI2 | c.606C>T p.S202= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs146181686; ClinVar: uncertain significance; called by mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 99/553 reads (18%) | called by muse, mutect2, varscan2
- GTF2F1 | c.879G>A p.Q293= | Silent (SNP) | VAF 20/266 reads (8%) | catalogued as COSV66725853; called by muse, mutect2
- H2BC4 | c.162C>T p.G54= | Silent (SNP) | VAF 17/260 reads (7%) | catalogued as rs1169618682, COSV58414773; called by muse, mutect2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 108/258 reads (42%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 102/247 reads (41%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HEPACAM | c.381C>T p.T127= | Silent (SNP) | VAF 19/328 reads (6%) | catalogued as rs766390439, COSV53432420; called by muse, mutect2
- HIVEP3 | c.1014C>T p.P338= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 69/189 reads (37%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 143/420 reads (34%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IBTK | c.2991C>T p.N997= | Silent (SNP) | VAF 45/132 reads (34%) | called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 130/313 reads (42%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- IL6ST | c.2412C>A p.G804= | Silent (SNP) | VAF 12/213 reads (6%) | catalogued as rs200386892, COSV61139608; called by muse, mutect2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 80/173 reads (46%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 120/395 reads (30%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KIF7 | c.786G>A p.T262= | Silent (SNP) | VAF 20/476 reads (4%) | catalogued as rs1054963355, COSV67998466; called by muse, mutect2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 24/255 reads (9%) | called by muse, mutect2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 77/169 reads (46%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 62/330 reads (19%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 52/96 reads (54%) | catalogued as rs1195603578; called by muse, mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 238/612 reads (39%) | called by muse, mutect2, varscan2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAP3K21 | c.939C>T p.P313= | Silent (SNP) | VAF 23/357 reads (6%) | catalogued as rs1294798585, COSV100786205, COSV100786301; called by muse, mutect2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 102/257 reads (40%) | called by muse, mutect2, varscan2
- MCF2L | c.3273C>T p.G1091= (on ENST00000375608; = p.G1059= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/258 reads (11%) | catalogued as rs745429431; called by muse, mutect2, varscan2
- MCTP2 | c.174T>C p.A58= | Silent (SNP) | VAF 13/212 reads (6%) | catalogued as rs994648268; called by muse, mutect2
- MED13 | c.5769T>C p.F1923= | Silent (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- MED13L | c.5847C>T p.C1949= | Silent (SNP) | VAF 21/452 reads (5%) | catalogued as rs1207291009; called by muse, mutect2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 62/137 reads (45%) | called by muse, mutect2, varscan2
- MUC16 | c.32421T>C p.T10807= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- MVP | c.1227C>A p.T409= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NPHP3 | c.3237G>A p.Q1079= | Silent (SNP) | VAF 24/286 reads (8%) | called by muse, mutect2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 201/479 reads (42%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- NRXN2 | c.297C>T p.A99= | Silent (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
- NUP62 | c.1377C>T p.N459= | Silent (SNP) | VAF 24/428 reads (6%) | called by muse, mutect2
- OR2V2 | c.63C>T p.H21= | Silent (SNP) | VAF 68/208 reads (33%) | called by muse, mutect2
- OR52W1 | c.496C>T p.L166= | Silent (SNP) | VAF 12/374 reads (3%) | called by muse, mutect2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 168/382 reads (44%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2
- P2RY14 | c.501T>C p.V167= | Silent (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- P2RY4 | c.841C>T p.L281= | Silent (SNP) | VAF 22/354 reads (6%) | catalogued as rs1472982109; called by muse, mutect2
- PAFAH1B2 | c.306A>G p.V102= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as rs1392111813; called by muse, mutect2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 103/259 reads (40%) | called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 157/332 reads (47%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 129/452 reads (29%) | called by muse, mutect2, varscan2
- PGLYRP3 | c.921G>A p.L307= | Silent (SNP) | VAF 22/688 reads (3%) | called by muse, mutect2
- PHF19 | c.1692T>C p.P564= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs868536698; called by muse, mutect2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 102/264 reads (39%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PICK1 | c.1161G>A p.E387= | Silent (SNP) | VAF 73/194 reads (38%) | catalogued as rs1266755272; called by mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, mutect2
- PKHD1L1 | c.5496A>G p.P1832= | Silent (SNP) | VAF 11/247 reads (4%) | called by muse, mutect2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 89/437 reads (20%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLEC | c.4803C>T p.T1601= (on ENST00000322810 / NM_201380.4; = p.T1491= on NM_000445.5) | Silent (SNP) | VAF 23/787 reads (3%) | catalogued as rs372029672; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 146/314 reads (46%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POC5 | c.1254A>G p.P418= (on ENST00000428202 / NM_001099271.2; = p.P393= on NM_152408.2) | Silent (SNP) | VAF 24/484 reads (5%) | called by muse, mutect2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 57/303 reads (19%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 66/314 reads (21%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2, varscan2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 214/487 reads (44%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 103/217 reads (47%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 98/257 reads (38%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 116/260 reads (45%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RIC8A | c.1071G>A p.L357= (on ENST00000526104 / NM_001286134.1; = p.L363= on NM_021932.5) | Silent (SNP) | VAF 20/285 reads (7%) | called by muse, mutect2
- RTEL1 | c.2007G>A p.Q669= | Silent (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- SEC24C | c.2955T>C p.N985= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as rs1317312801; called by muse, mutect2
- SEMA6A | c.729T>C p.Y243= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs774596346; called by muse, mutect2, varscan2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 123/308 reads (40%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 250/649 reads (39%) | called by muse, varscan2
- SLC12A1 | c.2661T>C p.H887= | Silent (SNP) | VAF 20/171 reads (12%) | catalogued as rs1204413639; called by muse, mutect2, varscan2
- SLC38A10 | c.879G>A p.R293= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs890805935; called by muse, mutect2
- SLC45A1 | c.588C>A p.T196= | Silent (SNP) | VAF 38/588 reads (6%) | called by muse, mutect2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 85/226 reads (38%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.489C>A p.I163= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 80/212 reads (38%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SNAP23 | c.255C>T p.C85= | Silent (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/149 reads (48%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 54/290 reads (19%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SPG11 | c.618G>A p.T206= | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as rs766634102, COSV55992906; called by muse, mutect2
- SPOCD1 | c.2844A>G p.S948= | Silent (SNP) | VAF 31/394 reads (8%) | called by muse, mutect2
- SRF | c.888C>A p.S296= | Silent (SNP) | VAF 56/626 reads (9%) | called by muse, mutect2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 50/98 reads (51%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1638T>C p.H546= | Silent (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
- STARD8 | c.2943G>T p.R981= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV52930878; called by muse, mutect2
- STRA6 | c.417T>C p.T139= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 160/400 reads (40%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 51/252 reads (20%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 84/185 reads (45%) | called by muse, mutect2, varscan2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 130/276 reads (47%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 63/128 reads (49%) | called by muse, mutect2, varscan2
- TNXB | c.8856G>A p.V2952= (on ENST00000647633; = p.V2705= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/220 reads (4%) | catalogued as rs1343000989; called by muse, mutect2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 67/175 reads (38%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 53/249 reads (21%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 196/515 reads (38%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 68/388 reads (18%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 44/202 reads (22%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 148/381 reads (39%) | called by muse, mutect2, varscan2
- VWC2 | c.492G>A p.A164= | Silent (SNP) | VAF 24/645 reads (4%) | catalogued as rs1261167091; called by muse, mutect2
- WDR90 | c.759G>A p.Q253= | Silent (SNP) | VAF 16/350 reads (5%) | called by muse, mutect2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 174/405 reads (43%) | called by muse, mutect2, varscan2
- ZBTB7C | c.1587C>T p.S529= | Silent (SNP) | VAF 9/222 reads (4%) | called by muse, mutect2
- ZEB2 | c.3195A>G p.S1065= | Silent (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- ZNF213 | c.1167C>T p.A389= | Silent (SNP) | VAF 12/275 reads (4%) | called by muse, mutect2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 57/179 reads (32%) | called by muse, mutect2, varscan2
- ZNF721 | c.2109T>C p.H703= (on ENST00000338977; = p.H715= on NM_133474.4) | Silent (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- ZNF837 | c.1086G>A p.P362= | Silent (SNP) | VAF 15/159 reads (9%) | catalogued as rs777300573; called by muse, mutect2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 62/146 reads (42%) | called by muse, mutect2, varscan2
- ZNF853 | c.1224G>A p.Q408= | Silent (SNP) | VAF 10/239 reads (4%) | called by muse, mutect2
- ZSWIM5 | c.3456C>A p.P1152= | Silent (SNP) | VAF 24/397 reads (6%) | called by muse, mutect2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 46/117 reads (39%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 91/211 reads (43%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- AC116366.2 | c.-638+7360G>A | Intron (SNP) | VAF 56/542 reads (10%) | called by muse, mutect2, varscan2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 101/269 reads (38%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.1900+47G>A | Intron (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- ADGRE4P | n.1286G>A | RNA (SNP) | VAF 10/92 reads (11%) | catalogued as rs372326442; called by muse, varscan2
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 176/1032 reads (17%) | called by muse, varscan2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 152/379 reads (40%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 39/177 reads (22%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 31/77 reads (40%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 9/50 reads (18%) | catalogued as rs1383985581; called by muse, mutect2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 35/207 reads (17%) | called by muse, mutect2, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- CHEK2 | c.*1A>G | 3'UTR (SNP) | VAF 17/448 reads (4%) | called by muse, mutect2
- COCH | chr14:30894909 A>T | 3'Flank (SNP) | VAF 5/48 reads (10%) | catalogued as rs1317914695, COSV53549614; called by muse, mutect2
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 56/492 reads (11%) | called by muse, mutect2, varscan2
- CPZ | c.1228-790G>A | Intron (SNP) | VAF 25/483 reads (5%) | catalogued as rs575495423; called by muse, mutect2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 108/278 reads (39%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- CUX2 | c.63+65749C>T | Intron (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 141/412 reads (34%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DDX55 | c.1164+15G>A | Intron (SNP) | VAF 14/136 reads (10%) | catalogued as rs754189427; called by mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 109/287 reads (38%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 30/90 reads (33%) | catalogued as rs1446348498; called by mutect2, pindel
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 58/131 reads (44%) | catalogued as rs779918120, COSV58541974; called by muse, mutect2, varscan2
- ENAH | c.803-282del | Intron (DEL) | VAF 28/246 reads (11%) | called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 52/145 reads (36%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 77/342 reads (23%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.217G>A | RNA (SNP) | VAF 13/376 reads (3%) | called by muse, mutect2
- GABPB1 | c.1036-3590G>A | Intron (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 28/139 reads (20%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 83/240 reads (35%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- GPSM1 | c.1207+108C>T | Intron (SNP) | VAF 26/508 reads (5%) | catalogued as rs782357766; called by muse, mutect2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 84/242 reads (35%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 74/189 reads (39%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- KDM4C | c.2994+116del | Intron (DEL) | VAF 42/158 reads (27%) | catalogued as COSV67183745; called by mutect2, varscan2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 33/243 reads (14%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 22/163 reads (13%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 64/192 reads (33%) | called by muse, mutect2, varscan2
- MAP9 | c.708+52del | Intron (DEL) | VAF 7/73 reads (10%) | called by mutect2, pindel
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 91/194 reads (47%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 117/269 reads (43%) | called by muse, mutect2, varscan2
- MT1M | c.94+39C>T | Intron (SNP) | VAF 45/430 reads (10%) | catalogued as rs751934155; called by muse, mutect2, varscan2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 14/44 reads (32%) | catalogued as rs746639059; called by mutect2, pindel, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 68/321 reads (21%) | catalogued as rs1305952989, COSV58516256; called by muse, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 48/100 reads (48%) | catalogued as rs1349876274; called by mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 16/70 reads (23%) | catalogued as rs749732874; called by mutect2, pindel, varscan2
- NGRN | chr15:90275470 T>G | 3'Flank (SNP) | VAF 20/291 reads (7%) | called by muse, mutect2
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 50/153 reads (33%) | catalogued as rs1295311548; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 46/102 reads (45%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 41/134 reads (31%) | catalogued as rs771823733; called by mutect2, varscan2
- OR7A2P | n.362G>A | RNA (SNP) | VAF 16/234 reads (7%) | catalogued as rs528570028; called by muse, mutect2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 204/587 reads (35%) | called by mutect2, pindel, varscan2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 24/130 reads (18%) | catalogued as rs539574874; called by muse, mutect2, varscan2
- PDCD6IP | c.210-984G>A | Intron (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 68/152 reads (45%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 68/181 reads (38%) | called by muse, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 27/148 reads (18%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- POLM | c.714+75C>A | Intron (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 106/237 reads (45%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 50/456 reads (11%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 84/218 reads (39%) | called by muse, mutect2, varscan2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 61/174 reads (35%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 34/284 reads (12%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49891790 A>G | 5'Flank (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 41/115 reads (36%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 215/563 reads (38%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SDCCAG8 | c.740+18A>G | Intron (SNP) | VAF 9/273 reads (3%) | catalogued as rs1394032819; called by muse, mutect2
- SHFL | c.196-14C>T | Intron (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 92/529 reads (17%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 80/368 reads (22%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 51/140 reads (36%) | called by mutect2, pindel, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 42/119 reads (35%) | called by mutect2, pindel, varscan2
- STK19 | c.567+22G>A | Intron (SNP) | VAF 30/352 reads (9%) | catalogued as rs1183671537; called by muse, mutect2
- SZRD1 | c.52-3715T>G | Intron (SNP) | VAF 13/374 reads (3%) | catalogued as COSV65043547; called by muse, mutect2
- TPRXL | n.752C>T | RNA (SNP) | VAF 23/204 reads (11%) | catalogued as rs192562800; called by muse, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 45/112 reads (40%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- YWHAH | c.87+657T>A | Intron (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
- ZDHHC23 | c.1217-20del | Intron (DEL) | VAF 9/70 reads (13%) | catalogued as rs767083235; called by mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 14/118 reads (12%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- ZNF584 | c.292+231T>C | Intron (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 52/143 reads (36%) | called by mutect2, pindel, varscan2
